Somatic mutation profile of tumor specimen TCGA-B5-A0K6-01A (aliquot TCGA-B5-A0K6-01A-11W-A062-09) from TCGA case TCGA-B5-A0K6, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 58.9 years (21,515 days).
Specimen TCGA-B5-A0K6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9e4dba9-760a-4c0e-a947-75b8083be9f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A0K6-10A (Blood Derived Normal), aliquot TCGA-B5-A0K6-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83868fe9-d726-437c-bfe0-0dc51fc9be29

The open-access MAF lists 429 somatic variants for this specimen: 338 protein-altering or splice-affecting, 81 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 251, Silent 81, Frame Shift Del 52, Nonsense Mutation 17, Frame Shift Ins 8, Splice Region 5, Splice Site 4, 5'Flank 3, 3'UTR 3, 3'Flank 2, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANOS1 | c.1891C>T p.R631* | Nonsense Mutation (SNP) | VAF 24/45 reads (53%) | catalogued as rs886039395, CM040759, COSV52915923; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4113del p.K1371Nfs*65 | Frame Shift Del (DEL) | VAF 22/193 reads (11%) | catalogued as rs752661599, COSV100863757; ClinVar: pathogenic; called by mutect2, varscan2
- COL4A5 | c.1376del p.P459Qfs*15 | Frame Shift Del (DEL) | VAF 113/949 reads (12%) | catalogued as rs104886113, CD961911; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CTNNB1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 11/98 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: pathogenic / likely pathogenic /  other; called by muse, mutect2, varscan2
- GATA6 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs387906819, CM1110614, COSV52524456; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ITGB4 | c.600del p.F201Sfs*9 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | catalogued as rs752657203, COSV52322249, COSV52323301; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 17/38 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 50/258 reads (19%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.328_330del p.E110del | In Frame Del (DEL) | VAF 94/274 reads (34%) | hotspot (GDC flag); called by pindel, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 22/59 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 24/394 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs121913293, CM074467, COSV64288569, COSV64310838; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 81/364 reads (22%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SCN1A | c.5348C>T p.A1783V (on ENST00000303395 / NM_001202435.3; = p.A1772V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/600 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs121917921, CM076501, COSV57658839; ClinVar: pathogenic; called by muse, mutect2
- ABCA5 | c.3596A>G p.D1199G | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs766984449, COSV67015726; called by muse, mutect2, varscan2
- ABCA8 | c.391A>G p.N131D | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52194211; called by muse, mutect2
- ABI3BP | c.1027A>T p.T343S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52528274, COSV52529065; called by muse, mutect2, varscan2
- ABR | c.896C>T p.T299M (on ENST00000302538 / NM_021962.5; = p.T262M on NM_001092.5) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.39); catalogued as COSV52141498; called by muse, mutect2
- AC004922.1 | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV53555482; called by muse, mutect2, varscan2
- ADAM7 | c.1879G>A p.V627I | Missense Mutation (SNP) | VAF 74/305 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.084); catalogued as rs867183559, COSV51535035; called by muse, mutect2, varscan2
- ADARB2 | c.2007C>A p.H669Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as COSV67181833; called by muse, mutect2, varscan2
- ADCY2 | c.2776-1G>T p.X926_splice | Splice Site (SNP) | VAF 5/57 reads (9%) | catalogued as COSV57858955; called by muse, mutect2
- ADGRL2 | c.4087C>A p.L1363I (on ENST00000370717 / NM_001366005.1; = p.L1307I on NM_012302.4) | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.471); catalogued as COSV54652234; called by muse, mutect2, varscan2
- ADGRV1 | c.3163G>A p.V1055I | Missense Mutation (SNP) | VAF 115/390 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV67978465; called by muse, mutect2, varscan2
- ADORA2A | c.620A>G p.Q207R | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58377901; called by muse, mutect2, varscan2
- AGGF1 | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 51/576 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.086); catalogued as COSV57227735; called by muse, mutect2
- AGXT2 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV51483904; called by muse, mutect2
- AHNAK2 | c.1673A>G p.E558G | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV60907639; called by muse, mutect2
- AK5 | c.980C>T p.A327V (on ENST00000354567 / NM_174858.3; = p.A301V on NM_012093.4) | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV60967612; called by muse, mutect2, varscan2
- AKAP13 | c.4597G>A p.V1533M | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs147374322, COSV100773916; called by muse, mutect2, varscan2
- ALMS1 | c.10421G>A p.R3474H | Missense Mutation (SNP) | VAF 70/293 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757108070, COSV52502679, COSV52520228; called by muse, mutect2, varscan2
- ANO9 | c.2061del p.D688Ifs*44 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs1197942333; called by mutect2, pindel
- APBB3 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); catalogued as COSV60051491; called by muse, mutect2, varscan2
- APOL3 | c.1012C>T p.R338W (on ENST00000349314 / NM_145640.2; = p.R267W on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs765336780, COSV62579174; called by muse, mutect2, varscan2
- ARL14EP | c.266dup p.N89Kfs*6 | Frame Shift Ins (INS) | VAF 38/198 reads (19%) | catalogued as rs1247324796; called by mutect2, varscan2
- ART3 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 9/242 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV61913072; called by muse, mutect2
- ASB13 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.227); catalogued as rs774054143, COSV63089900; called by muse, mutect2, varscan2
- ASGR2 | c.712A>G p.T238A | Missense Mutation (SNP) | VAF 19/383 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV54689264; called by muse, mutect2
- ASPH | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.018); catalogued as rs767403241, COSV62857903; called by muse, mutect2, varscan2
- ASPHD1 | c.619C>G p.R207G | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV58097126, COSV58103625; called by muse, mutect2, varscan2
- ASPRV1 | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.19); catalogued as COSV57227379; called by muse, mutect2
- ATAD3B | c.706C>T p.R236W (on ENST00000308647; = p.R342W on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs1557807620, COSV58019192; called by muse, mutect2
- ATF1 | c.130T>G p.S44A | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.663); catalogued as COSV50393978; called by muse, mutect2, varscan2
- AXIN1 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51983237; called by muse, mutect2, varscan2
- BCL11A | c.1825G>A p.D609N (on ENST00000335712 / NM_001365609.1; = p.D643N on NM_018014.4) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.776); catalogued as rs62142605, COSV59624324; called by muse, mutect2, varscan2
- BCOR | c.2482G>A p.A828T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV60699711; called by muse, mutect2, varscan2
- BMF | c.14_15del p.Q5Lfs*8 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as COSV55018621; called by mutect2, pindel, varscan2
- BPIFA1 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 119/548 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); catalogued as rs778951783, COSV62823874; called by muse, mutect2, varscan2
- C11orf80 | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV60927981; called by muse, mutect2, varscan2
- CAMSAP3 | c.3325+1G>A p.X1109_splice | Splice Site (SNP) | VAF 11/28 reads (39%) | catalogued as COSV50330825; called by muse, mutect2, varscan2
- CAPRIN2 | c.2588C>A p.P863H | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.416); catalogued as rs1342908119, COSV51830417; called by muse, mutect2
- CASS4 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs199573867, COSV64385387; called by muse, mutect2, varscan2
- CATSPERE | c.1357T>C p.S453P | Missense Mutation (SNP) | VAF 112/611 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV63675823; called by muse, mutect2, varscan2
- CCDC88A | c.2335del p.I779Sfs*4 | Frame Shift Del (DEL) | VAF 68/243 reads (28%) | catalogued as COSV55059558; called by mutect2, pindel, varscan2
- CD1D | c.566G>A p.S189N | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV63808393; called by muse, mutect2
- CD300C | c.654G>A p.W218* | Nonsense Mutation (SNP) | VAF 4/76 reads (5%) | catalogued as COSV100423199, COSV58169544; called by muse, mutect2
- CDK9 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as COSV64723350; called by muse, mutect2, varscan2
- CEACAM1 | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs145087706; called by muse, mutect2, varscan2
- CFP | c.1084G>T p.G362W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55949667; called by muse, mutect2, varscan2
- CHD1L | c.1341T>A p.N447K | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs145656868; called by muse, mutect2, varscan2
- CHD3 | c.3233G>A p.R1078Q | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV57872491; called by muse, mutect2, varscan2
- CHRNA7 | c.650A>G p.Y217C | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60967735; called by muse, mutect2, varscan2
- CIC | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50547229; called by muse, mutect2
- CLCN4 | c.1756G>A p.V586M | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV66465149; called by muse, mutect2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 38/139 reads (27%) | catalogued as rs374805044; called by mutect2, varscan2
- CPAMD8 | c.3153del p.H1052Ifs*127 (on ENST00000651564; = p.H1005Ifs*127 on NM_015692.5) | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | catalogued as rs750161916, COSV71597321; called by mutect2, pindel, varscan2
- CRNKL1 | c.2504C>T p.A835V | Missense Mutation (SNP) | VAF 37/364 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); catalogued as COSV58548052; called by muse, mutect2, varscan2
- CSH2 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV100400317, COSV61080007; called by muse, mutect2, varscan2
- CUBN | c.9037G>T p.V3013F | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs1241849194, COSV64707816; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCTN1 | c.1740G>T p.Q580H | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62619595; called by muse, mutect2
- DCTN5 | c.134A>G p.D45G | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV55614690; called by muse, mutect2, varscan2
- DDX46 | c.2125C>T p.R709W | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867986546, COSV62798435; called by muse, mutect2, varscan2
- DES | c.580C>T p.L194= | Splice Region (SNP) | VAF 8/40 reads (20%) | catalogued as COSV64659816; called by muse, mutect2, varscan2
- DHRS9 | c.157G>T p.G53* | Nonsense Mutation (SNP) | VAF 53/214 reads (25%) | catalogued as COSV59138796; called by muse, mutect2, varscan2
- DNAH2 | c.2129C>A p.P710Q | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV66716311; called by muse, mutect2, varscan2
- DNAJC5B | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs761558528, COSV52535718; called by muse, mutect2, varscan2
- DOCK2 | c.3304G>T p.E1102* | Nonsense Mutation (SNP) | VAF 27/742 reads (4%) | catalogued as COSV56941991; called by muse, mutect2
- DOCK9 | c.283A>G p.T95A (on ENST00000376460 / NM_001366676.2; = p.T96A on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as COSV59619581; called by muse, mutect2, varscan2
- DSE | c.2032G>T p.G678* | Nonsense Mutation (SNP) | VAF 29/151 reads (19%) | catalogued as COSV59061830; called by muse, mutect2, varscan2
- DSP | c.4415C>T p.A1472V | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs1272181488, COSV65791090; called by muse, mutect2, varscan2
- DST | c.19745G>A p.R6582Q (on ENST00000361203 / NM_001374722.1; = p.R4279Q on NM_015548.5) | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs754316339, COSV54997586; called by muse, mutect2
- EDNRB | c.1061C>T p.A354V (on ENST00000377211 / NM_001201397.1; = p.A264V on NM_000115.5) | Missense Mutation (SNP) | VAF 11/224 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.037); catalogued as rs1212186974, COSV57518929; ClinVar: uncertain significance; called by muse, mutect2
- EFNB1 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV52660965; called by muse, mutect2
- EID2B | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as rs774688840, COSV58318760; called by muse, mutect2, varscan2
- EIF4G1 | c.3706G>A p.A1236T (on ENST00000346169 / NM_198241.3; = p.A1041T on NM_004953.5) | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV59989097; called by muse, mutect2
- ELK4 | c.166T>C p.Y56H | Missense Mutation (SNP) | VAF 16/464 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56983999; called by muse, mutect2
- EPRS1 | c.3980G>A p.C1327Y | Missense Mutation (SNP) | VAF 30/464 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV65097100; called by muse, mutect2
- ERC2 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55600676; called by muse, mutect2
- ERI3 | c.933C>T p.D311= | Splice Region (SNP) | VAF 15/41 reads (37%) | catalogued as rs773605425, COSV59999922; called by muse, mutect2, varscan2
- FAM83B | c.2094G>T p.K698N | Missense Mutation (SNP) | VAF 69/274 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV60919326, COSV60925211; called by muse, mutect2, varscan2
- FBXO28 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV64799504, COSV64799923; called by muse, mutect2, varscan2
- FBXO33 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 63/238 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as rs758089884, COSV53233277; called by muse, mutect2, varscan2
- FES | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1210252844, COSV51574609; called by muse, mutect2, varscan2
- FGD2 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs142160745; called by muse, mutect2, varscan2
- FLG2 | c.6416C>T p.A2139V | Missense Mutation (SNP) | VAF 52/962 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); catalogued as rs767255975, COSV66166633; called by muse, mutect2
- FMNL3 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV53297865; called by muse, mutect2
- GATB | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); catalogued as COSV56128754; called by muse, mutect2, varscan2
- GBF1 | c.4420G>A p.G1474R (on ENST00000369983 / NM_001377137.1; = p.G1473R on NM_004193.3) | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.899); catalogued as rs1217833812, COSV64142771; called by muse, mutect2
- GMEB2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.401); catalogued as rs777285269, COSV56605652; called by muse, mutect2, varscan2
- GOLGA8B | c.1796C>T p.P599L | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as rs1232957889, COSV50987898; called by muse, mutect2, varscan2
- GPR156 | c.260T>C p.L87P | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59938029; called by muse, mutect2
- GPR6 | c.934T>A p.Y312N | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51570989; called by muse, mutect2, varscan2
- GSAP | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs375125347; called by muse, mutect2, varscan2
- GTF2H4 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as rs577023692, COSV52557404; called by muse, mutect2
- GTPBP10 | c.967C>A p.P323T | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV55986227; called by muse, mutect2, varscan2
- GUCY1B1 | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV52373656; called by muse, mutect2
- GYS1 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as rs754705699, COSV54401286, COSV99621045; called by muse, mutect2, varscan2
- H2AC8 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); catalogued as COSV55126168; called by muse, mutect2, varscan2
- HCN1 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1333872397, COSV100298381, COSV57492101, COSV57537055; called by muse, mutect2, varscan2
- HECW2 | c.2128G>A p.V710I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.427); catalogued as COSV53649418; called by muse, mutect2, varscan2
- HHLA2 | c.141A>G p.I47M | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV63315626; called by muse, mutect2
- HIPK1 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV61245875; called by muse, mutect2, varscan2
- HNRNPK | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 58/622 reads (9%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV61088203; called by muse, mutect2
- HOATZ | c.62del p.P21Rfs*79 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | catalogued as rs570525399; called by mutect2, pindel, varscan2
- HPSE2 | c.57del p.A20Rfs*3 | Frame Shift Del (DEL) | VAF 20/103 reads (19%) | catalogued as COSV65189625; called by mutect2, pindel, varscan2
- IFT140 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV68485853; called by muse, mutect2
- IFT27 | c.551C>T p.A184V (on ENST00000433985 / NM_001363003.2; = p.A183V on NM_006860.5) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV61415914; called by muse, mutect2, varscan2
- IGF2R | c.1021C>A p.L341I | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63626357; called by muse, mutect2
- IGSF9B | c.3854C>A p.P1285H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.276); catalogued as COSV58063596; called by muse, mutect2
- IQSEC2 | c.1051G>A p.A351T (on ENST00000642864 / NM_001111125.3; = p.A146T on NM_015075.2) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64723364; called by mutect2, varscan2
- IQUB | c.1669C>A p.L557I | Missense Mutation (SNP) | VAF 24/522 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61236853; called by muse, mutect2
- ITLN2 | c.179G>T p.C60F | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.492); catalogued as COSV63537369; called by muse, mutect2
- JRKL | c.1454C>T p.T485I | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.272); catalogued as COSV53592064; called by muse, mutect2, varscan2
- KBTBD6 | c.1148C>T p.T383I | Missense Mutation (SNP) | VAF 11/264 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.076); catalogued as COSV65270866; called by muse, mutect2
- KCNU1 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.506); catalogued as COSV67753081; called by muse, mutect2
- KIAA1210 | c.3266G>T p.W1089L | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.048); catalogued as COSV68175430; called by muse, mutect2
- KIDINS220 | c.5006C>T p.A1669V | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.037); catalogued as COSV56750431; called by muse, mutect2, varscan2
- KIF15 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs147576633; called by muse, varscan2
- KIF2B | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs1479427821, COSV52127121; called by muse, mutect2, varscan2
- KIRREL2 | c.1953del p.C652Afs*79 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | catalogued as rs761116739, COSV52880030; called by mutect2, pindel, varscan2
- KRT40 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 60/209 reads (29%) | catalogued as COSV66695970; called by muse, mutect2, varscan2
- KSR2 | c.1001G>A p.S334N | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1207425275, COSV56665689; called by muse, mutect2
- LAMA1 | c.1771G>A p.V591M | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV67532064; called by muse, mutect2
- LCE4A | c.8G>A p.C3Y | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.292); catalogued as COSV59266294; called by muse, mutect2
- LEPR | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 58/262 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs748033432, COSV60747032, COSV99051282; called by muse, mutect2, varscan2
- LGALS14 | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.055); catalogued as rs111361406, COSV62372178; called by muse, mutect2, varscan2
- LIMA1 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57963840; called by muse, mutect2
- LIN7A | c.562T>C p.Y188H | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54017929; called by muse, mutect2, varscan2
- LPAR1 | c.976C>A p.L326I | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.443); catalogued as COSV62687105, COSV62690919; called by muse, mutect2, varscan2
- LPAR3 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as COSV65452658; called by muse, mutect2, varscan2
- MAN2B1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as rs1303897908, COSV54417318; called by muse, mutect2, varscan2
- MAP2K1 | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV61068599; called by muse, mutect2
- MAP3K19 | c.3459C>A p.N1153K | Missense Mutation (SNP) | VAF 11/245 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV59636590; called by muse, mutect2
- MAPKAPK3 | c.704+1G>A p.X235_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | catalogued as COSV63596804; called by muse, mutect2
- MDC1 | c.4498G>A p.A1500T | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148215318; called by mutect2, varscan2
- MFSD9 | c.1326del p.S443Afs*6 | Frame Shift Del (DEL) | VAF 13/72 reads (18%) | catalogued as rs769987847; called by mutect2, pindel, varscan2
- MTBP | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.356); catalogued as COSV59960923; called by muse, mutect2, varscan2
- MTCL1 | c.3246G>T p.Q1082H (on ENST00000306329 / NM_001378206.1; = p.Q763H on NM_015210.4) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV60403191; called by muse, mutect2, varscan2
- MTFR2 | c.562T>C p.S188P | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV63078614; called by muse, mutect2, varscan2
- MUC17 | c.2632G>A p.A878T | Missense Mutation (SNP) | VAF 33/397 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs766298778, COSV60279921; called by muse, mutect2
- MUC4 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.722); catalogued as rs540356612, COSV62129250; called by muse, mutect2
- MYEF2 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 32/319 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs143505455; called by muse, mutect2, varscan2
- MYH15 | c.4049G>A p.R1350H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs768579358, COSV56304421; called by mutect2, varscan2
- MYH9 | c.3091G>T p.D1031Y | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV53381943, COSV99339257; called by muse, mutect2, varscan2
- MYLK | c.3774T>G p.F1258L | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV60604716; called by muse, mutect2
- NAA20 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 92/376 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs765991569, COSV58548048; called by muse, varscan2
- NAA25 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); catalogued as rs765828147, COSV55701958; called by muse, mutect2, varscan2
- NAA30 | c.695C>A p.T232N | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV53647995; called by muse, mutect2, varscan2
- NAPSA | c.997del p.V333Sfs*58 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | catalogued as rs568951683; called by mutect2, pindel, varscan2
- NBN | c.1577C>T p.T526I | Missense Mutation (SNP) | VAF 23/341 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV55371149; called by muse, mutect2
- NCOA7 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs779767564, COSV57652307; called by muse, mutect2
- NEUROD4 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 94/324 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54470415, COSV54474557; called by muse, mutect2, varscan2
- NFRKB | c.932del p.K311Rfs*13 (on ENST00000446488 / NM_001143835.2; = p.K336Rfs*13 on NM_006165.3) | Frame Shift Del (DEL) | VAF 28/136 reads (21%) | catalogued as rs149369172, COSV58756820; called by mutect2, varscan2
- NSD3 | c.701T>C p.V234A | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs754547374, COSV57617155; called by muse, mutect2, varscan2
- NT5C2 | c.290C>A p.T97N | Missense Mutation (SNP) | VAF 48/529 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58414777; called by muse, mutect2
- NT5C3A | c.354G>A p.K118= (on ENST00000610140 / NM_001374335.1; = p.K84= on NM_016489.13) | Splice Region (SNP) | VAF 8/25 reads (32%) | catalogued as rs1279090004, COSV54236861; called by muse, mutect2, varscan2
- NTF3 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV58417158, COSV58417973; called by muse, mutect2, varscan2
- NTRK2 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 92/398 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV52853772, COSV52887144; called by muse, mutect2, varscan2
- NUDC | c.875A>T p.Y292F | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.179); catalogued as COSV57670817; called by muse, mutect2, varscan2
- NUP88 | c.1835G>T p.R612M | Missense Mutation (SNP) | VAF 88/386 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52582687; called by muse, mutect2, varscan2
- ONECUT2 | c.1336A>G p.K446E | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.465); catalogued as COSV72152962; called by muse, mutect2
- OR51I2 | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 85/298 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1458892310, COSV58297894; called by muse, mutect2, varscan2
- OR56B1 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57722468; called by muse, mutect2, varscan2
- OR7A5 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 63/275 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.232); catalogued as COSV59234074; called by muse, mutect2, varscan2
- OR7C1 | c.384C>A p.H128Q | Missense Mutation (SNP) | VAF 61/253 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.213); catalogued as COSV50182863, COSV99934970; called by muse, mutect2, varscan2
- PAFAH1B2 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59166363; called by muse, mutect2, varscan2
- PAMR1 | c.302del p.G101Vfs*8 | Frame Shift Del (DEL) | VAF 106/471 reads (23%) | catalogued as rs751755759; called by mutect2, varscan2
- PARP6 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 17/522 reads (3%) | catalogued as COSV53002042; called by muse, mutect2
- PBRM1 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0.053); catalogued as COSV56261099; called by muse, mutect2
- PCDHA10 | c.707A>G p.D236G | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56477451; called by muse, mutect2, varscan2
- PCDHA4 | c.245G>A p.G82D | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554124011, COSV63538827; called by muse, mutect2, varscan2
- PCDHGA1 | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs746166561, COSV65294883, COSV65295920; called by muse, mutect2, varscan2
- PCDHGA8 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.258); catalogued as rs368785983, COSV99530075; called by muse, mutect2, varscan2
- PCLO | c.5102T>C p.M1701T | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs1358799489, COSV61616021; called by muse, mutect2
- PCTP | c.520T>A p.Y174N | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.121); catalogued as COSV52121894; called by muse, mutect2
- PDE12 | c.1429C>T p.H477Y | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs1461105762, COSV60818139; called by muse, mutect2, varscan2
- PDGFRB | c.2467G>A p.V823I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.265); catalogued as rs377442091; called by muse, mutect2, varscan2
- PDZD7 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV64645426; called by mutect2, varscan2
- PEX5 | c.1138G>A p.A380T (on ENST00000420616; = p.A372T on NM_000319.5) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56953389; called by muse, mutect2, varscan2
- PFKFB3 | c.623+2T>A p.X208_splice | Splice Site (SNP) | VAF 15/56 reads (27%) | catalogued as COSV57986774; called by muse, mutect2, varscan2
- PHF12 | c.2276A>G p.H759R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as rs776901944, COSV52017991; called by muse, mutect2, varscan2
- PI4KA | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 18/590 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV55403852; called by muse, mutect2
- PIGK | c.1049C>A p.P350H | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV63649531; called by muse, mutect2, varscan2
- PKD1L2 | c.2275G>A p.A759T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.242); catalogued as COSV55158082; called by muse, mutect2
- PKD2L2 | c.308C>A p.S103* | Nonsense Mutation (SNP) | VAF 10/232 reads (4%) | catalogued as COSV51794680; called by muse, mutect2
- PLA1A | c.712G>A p.G238R | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372028931; called by muse, mutect2, varscan2
- PLCH1 | c.3145A>G p.M1049V (on ENST00000340059 / NM_001130960.2; = p.M1041V on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs745760948, COSV58186529; called by muse, mutect2, varscan2
- POP5 | c.312A>G p.G104= | Splice Region (SNP) | VAF 6/78 reads (8%) | catalogued as COSV58043461; called by muse, mutect2
- PRB2 | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 48/1042 reads (5%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.047); catalogued as rs760418282, COSV66982163, COSV66982389; called by muse, mutect2
- PRDM2 | c.1627G>T p.E543* | Nonsense Mutation (SNP) | VAF 12/155 reads (8%) | catalogued as COSV52442833; called by muse, mutect2
- PRELP | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 45/240 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV58114832; called by muse, mutect2, varscan2
- PRF1 | c.629C>A p.P210H | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.059); catalogued as COSV64614394; called by muse, mutect2
- PSMD3 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV52856423; called by muse, mutect2, varscan2
- PSME4 | c.5413del p.T1805Pfs*69 | Frame Shift Del (DEL) | VAF 33/86 reads (38%) | catalogued as COSV101122574; called by mutect2, varscan2
- PTCHD4 | c.988G>T p.A330S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.219); catalogued as COSV59777629; called by muse, mutect2, varscan2
- PTEN | c.98T>G p.I33S | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV64289312, COSV64292633; called by muse, mutect2, varscan2
- PTGFRN | c.2035A>G p.I679V | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.617); catalogued as rs893372177, COSV67797713; called by muse, mutect2
- PTPRO | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 20/568 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV55503490; called by muse, mutect2
- PXDNL | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs200643962; called by muse, mutect2, varscan2
- R3HDM1 | c.1738C>T p.Q580* | Nonsense Mutation (SNP) | VAF 92/424 reads (22%) | catalogued as COSV51520848; called by muse, mutect2, varscan2
- RAD54L2 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56576964; called by muse, mutect2
- RAF1 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs759433668, COSV52574727; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBM12 | c.588G>A p.M196I | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV58289832; called by muse, mutect2
- RBM4 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1431308409, COSV59518019, COSV59520072; called by muse, mutect2, varscan2
- RGS3 | c.239G>A p.C80Y | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV58277002; called by muse, mutect2
- RHNO1 | c.62A>T p.Q21L | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.215); catalogued as COSV63485115; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 16/105 reads (15%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 71/289 reads (25%) | catalogued as rs752898741; called by mutect2, varscan2
- RPA2 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV57876843; called by muse, mutect2, varscan2
- RPL18A | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.317); catalogued as COSV55829740; called by muse, mutect2, varscan2
- RSPH9 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV64664060; called by muse, mutect2, varscan2
- RTKN | c.1127G>A p.G376E (on ENST00000272430 / NM_001015055.2; = p.G363E on NM_033046.2) | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV51961272; called by muse, mutect2
- RTKN2 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs777489242, COSV59521315; called by muse, mutect2, varscan2
- SATB1 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV58667462; called by muse, mutect2, varscan2
- SCN3A | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 22/399 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as COSV51801346; called by muse, mutect2
- SELE | c.208T>C p.Y70H | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60973891; called by muse, mutect2
- SEMA4F | c.1454A>C p.Q485P | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60281905; called by muse, mutect2, varscan2
- SEPTIN4 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57894196; called by muse, mutect2
- SERPINA3 | c.213G>T p.K71N | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as COSV67585234; called by muse, mutect2
- SIGLEC1 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs771244528, COSV52458581; called by mutect2, varscan2
- SIGLEC10 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV59478865; called by muse, mutect2, varscan2
- SIGLEC11 | c.1882G>T p.G628C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV68567494; called by mutect2, varscan2
- SLC16A4 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1224227217, COSV63915929; called by muse, mutect2
- SLC20A2 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV60601616; called by muse, mutect2
- SLC29A3 | c.1186T>A p.C396S | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.957); catalogued as COSV64384478; called by muse, mutect2, varscan2
- SLC37A2 | c.1042G>A p.G348S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs535796071, COSV53520187; called by mutect2, varscan2
- SLC4A7 | c.1619G>A p.S540N | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.94); PolyPhen benign (0.01); catalogued as COSV55394877; called by muse, mutect2
- SLC7A13 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52532467, COSV52536543; called by muse, mutect2, varscan2
- SLC8A2 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV52637626; called by muse, mutect2, varscan2
- SLCO1C1 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.557); catalogued as COSV56868350, COSV56872385; called by muse, mutect2, varscan2
- SLFN5 | c.708T>A p.C236* | Nonsense Mutation (SNP) | VAF 23/216 reads (11%) | catalogued as COSV55479838; called by muse, mutect2, varscan2
- SLU7 | c.473A>G p.Q158R | Missense Mutation (SNP) | VAF 85/327 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV51786462; called by muse, mutect2, varscan2
- SPEN | c.3181G>A p.A1061T | Missense Mutation (SNP) | VAF 13/271 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV65357694; called by muse, mutect2
- SPRR2E | c.5C>A p.S2Y | Missense Mutation (SNP) | VAF 157/770 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV64203563; called by muse, varscan2
- SRCAP | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs778348276, COSV52672270; called by muse, mutect2
- SRSF6 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs148216368; called by muse, mutect2, varscan2
- SSX1 | c.425del p.P142Qfs*34 | Frame Shift Del (DEL) | VAF 32/352 reads (9%) | catalogued as rs782023583, COSV100976380; called by mutect2, pindel
- ST8SIA1 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs777018933, COSV53950500; called by muse, mutect2, varscan2
- STARD3NL | c.296A>T p.D99V | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767198270, COSV50517933; called by muse, mutect2
- STAU2 | c.1091del p.N364Mfs*67 (on ENST00000524300 / NM_001164380.2; = p.N332Mfs*67 on NM_014393.2) | Frame Shift Del (DEL) | VAF 60/260 reads (23%) | catalogued as rs746501298; called by mutect2, varscan2
- STRADA | c.416C>T p.A139V (on ENST00000336174 / NM_001363786.1; = p.A102V on NM_153335.6) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.16); catalogued as COSV55561478; called by muse, mutect2, varscan2
- STXBP1 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as CM1510222, COSV64812104; called by muse, mutect2
- SUPT5H | c.684G>T p.E228D | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63238435; called by muse, mutect2, varscan2
- SUPT5H | c.2695C>T p.Q899* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as COSV63238440; called by muse, mutect2, varscan2
- SUV39H2 | c.743C>T p.T248I (on ENST00000354919 / NM_001193424.2; = p.T188I on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as COSV57952454; called by muse, mutect2, varscan2
- SVIL | c.5861G>C p.G1954A (on ENST00000355867 / NM_021738.3; = p.G1528A on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV63439737; called by muse, mutect2
- SVIL | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.058); catalogued as COSV63439748; called by muse, mutect2
- SYNJ2 | c.3018G>C p.L1006F | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV62895610; called by muse, mutect2, varscan2
- TACC3 | c.1669C>G p.Q557E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV57602752; called by muse, mutect2, varscan2
- TACC3 | c.2219G>A p.R740H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs1321749685, COSV57602764; called by muse, mutect2, varscan2
- TCERG1 | c.2203dup p.M735Nfs*8 | Frame Shift Ins (INS) | VAF 37/156 reads (24%) | catalogued as rs1402716842; called by mutect2, varscan2
- TEK | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs1286718039, COSV66227282, COSV66227429; called by muse, mutect2, varscan2
- TF | c.737G>A p.C246Y | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53917690; called by muse, mutect2, varscan2
- THBS2 | c.1540A>G p.I514V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV64677041; called by muse, mutect2, varscan2
- TIAM1 | c.218T>C p.L73P | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.816); catalogued as COSV54537577; called by muse, mutect2
- TLN2 | c.4718A>G p.N1573S | Missense Mutation (SNP) | VAF 60/378 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as COSV60885558; called by muse, mutect2, varscan2
- TMED10 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV57846898; called by muse, mutect2, varscan2
- TMEM161B | c.707G>A p.C236Y | Missense Mutation (SNP) | VAF 38/440 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56929221; called by muse, mutect2
- TMEM260 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as rs767176382, COSV55097061; called by muse, mutect2
- TMEM38A | c.758G>A p.C253Y | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51817971; called by muse, mutect2
- TNS2 | c.118C>T p.R40W (on ENST00000314250 / NM_170754.4; = p.R50W on NM_015319.2) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1230910886, COSV58574726; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1714C>T p.Q572* | Nonsense Mutation (SNP) | VAF 18/179 reads (10%) | catalogued as COSV54868306; called by muse, mutect2, varscan2
- TOR1B | c.625A>T p.I209F | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV52212297; called by muse, mutect2
- TP53TG5 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.028); catalogued as rs778649036, COSV65576895; called by muse, mutect2, varscan2
- TRAC | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760502192; called by muse, mutect2
- TREML4 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1401770093, COSV58384335; called by muse, mutect2, varscan2
- TRIM42 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV53880218; called by muse, mutect2
- TRPV4 | c.308C>A p.P103H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55679854; called by muse, mutect2, varscan2
- TRRAP | c.2686G>A p.G896S | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781890433, COSV100721956, COSV62838846; called by muse, mutect2
- TSHZ3 | c.1286C>A p.P429H | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV53664348; called by muse, mutect2
- TTF1 | c.821del p.K274Sfs*149 | Frame Shift Del (DEL) | VAF 63/264 reads (24%) | catalogued as rs770528448; called by mutect2, varscan2
- TTN | c.66194T>C p.L22065S (on ENST00000591111; = p.L14641S on NM_003319.4) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | PolyPhen possibly damaging (0.572); catalogued as rs1481919740, COSV59886768; called by muse, mutect2, varscan2
- TUT7 | c.161del p.K54Rfs*3 | Frame Shift Del (DEL) | VAF 36/232 reads (16%) | catalogued as rs369091628; called by mutect2, varscan2
- TXLNB | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.189); catalogued as rs1380289965, COSV64443098; called by muse, mutect2
- TXNDC11 | c.739del p.Q247Sfs*6 | Frame Shift Del (DEL) | VAF 21/119 reads (18%) | catalogued as rs751443151; called by mutect2, pindel, varscan2
- UBR3 | c.3728G>T p.G1243V | Missense Mutation (SNP) | VAF 15/328 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV55844537; called by muse, mutect2
- UBR4 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1429350047, COSV64382801; called by muse, mutect2, varscan2
- VPS13A | c.4632A>T p.V1544= | Splice Region (SNP) | VAF 19/215 reads (9%) | catalogued as COSV62425117, COSV62429221; called by muse, mutect2
- VWA3B | c.2269T>C p.S757P | Missense Mutation (SNP) | VAF 90/243 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV68240857; called by muse, mutect2, varscan2
- WAS | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.056); catalogued as rs368523950, COSV64996598; called by muse, mutect2, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | catalogued as rs762079039; called by mutect2, pindel, varscan2
- XDH | c.2569G>T p.V857F | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV65146909; called by muse, mutect2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 44/142 reads (31%) | catalogued as rs762052135; called by mutect2, varscan2
- ZCCHC8 | c.208C>T p.L70F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs1334870292, COSV60317029; called by muse, mutect2, varscan2
- ZDHHC4 | c.727G>A p.V243I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV60105931; called by mutect2, varscan2
- ZFHX4 | c.7945G>A p.V2649M | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50479490; called by muse, mutect2, varscan2
- ZFHX4 | c.9037G>A p.G3013R | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs1360488245, COSV50493419, COSV99254152; called by muse, mutect2, varscan2
- ZFP64 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 4/58 reads (7%) | catalogued as COSV53796351; called by muse, mutect2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 150/575 reads (26%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF280C | c.1789C>T p.R597* | Nonsense Mutation (SNP) | VAF 40/828 reads (5%) | catalogued as COSV63968469; called by muse, mutect2
- ZNF32 | c.40G>T p.G14* | Nonsense Mutation (SNP) | VAF 4/68 reads (6%) | catalogued as COSV65641468; called by muse, mutect2
- ZNF397 | c.105A>T p.K35N | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.047); catalogued as COSV54349864; called by muse, mutect2
- ZNF544 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.865); catalogued as COSV54134138; called by muse, mutect2, varscan2
- ZNF573 | c.911G>A p.C304Y (on ENST00000536220 / NM_001172692.1; = p.C246Y on NM_152360.3) | Missense Mutation (SNP) | VAF 18/406 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59823345; called by muse, mutect2
- ZNF610 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.886); catalogued as COSV58343554; called by muse, mutect2
- ZNF616 | c.810A>G p.I270M | Missense Mutation (SNP) | VAF 59/280 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs1304279190, COSV57509488; called by muse, mutect2, varscan2
- ZNHIT1 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); catalogued as COSV59312488; called by muse, mutect2
- ZRANB2 | c.901del p.R301Dfs*38 (on ENST00000370920 / NM_203350.3; = p.R301Dfs*12 on NM_005455.5) | Frame Shift Del (DEL) | VAF 44/363 reads (12%) | catalogued as COSV54672452; called by mutect2, varscan2
- ZSCAN20 | c.1685A>G p.Y562C | Missense Mutation (SNP) | VAF 72/150 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63681540; called by muse, mutect2, varscan2
- ABR | c.205del p.D69Mfs*23 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | called by mutect2, pindel, varscan2
- AGO1 | c.575del p.G192Vfs*20 | Frame Shift Del (DEL) | VAF 18/81 reads (22%) | called by mutect2, pindel, varscan2
- AKAP8L | c.1130del p.K377Sfs*44 | Frame Shift Del (DEL) | VAF 4/17 reads (24%) | called by mutect2, pindel, varscan2
- ANK3 | c.6309del p.F2103Lfs*7 | Frame Shift Del (DEL) | VAF 47/223 reads (21%) | called by mutect2, pindel, varscan2
- ARID1A | c.4899del p.M1634* | Frame Shift Del (DEL) | VAF 15/112 reads (13%) | called by mutect2, pindel, varscan2
- BTNL3 | c.285del p.R96Vfs*4 | Frame Shift Del (DEL) | VAF 8/73 reads (11%) | called by mutect2, pindel, varscan2
- C1orf122 | c.303G>T p.K101N | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- COPS3 | c.537dup p.H180Tfs*20 | Frame Shift Ins (INS) | VAF 15/112 reads (13%) | called by mutect2, pindel, varscan2
- DPPA2 | c.468_469del p.R156Sfs*8 | Frame Shift Del (DEL) | VAF 17/103 reads (17%) | called by pindel, varscan2
- GOLGA5 | c.330del p.F110Lfs*52 | Frame Shift Del (DEL) | VAF 50/208 reads (24%) | called by mutect2, pindel, varscan2
- IARS1 | c.3727del p.V1243* | Frame Shift Del (DEL) | VAF 23/113 reads (20%) | called by mutect2, pindel, varscan2
- IFNA13 | c.221dup p.A75Gfs*9 | Frame Shift Ins (INS) | VAF 32/109 reads (29%) | called by mutect2, varscan2
- KBTBD2 | c.693_694del p.R231Sfs*10 | Frame Shift Del (DEL) | VAF 14/112 reads (13%) | called by pindel, varscan2
- KIRREL2 | c.156dup p.L53Afs*6 | Frame Shift Ins (INS) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- LGALS3 | c.152del p.P51Qfs*64 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- MADD | c.3715_3718del p.S1239Ifs*20 | Frame Shift Del (DEL) | VAF 24/191 reads (13%) | called by mutect2, pindel, varscan2
- MEGF8 | c.5857del p.R1953Afs*90 (on ENST00000251268 / NM_001271938.2; = p.R1886Afs*90 on NM_001410.3) | Frame Shift Del (DEL) | VAF 18/89 reads (20%) | called by mutect2, pindel, varscan2
- MRE11 | c.963del p.F321Lfs*8 | Frame Shift Del (DEL) | VAF 46/219 reads (21%) | called by mutect2, pindel, varscan2
- MYO18B | c.419del p.K140Rfs*9 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- NEIL3 | c.513dup p.Q172Tfs*8 | Frame Shift Ins (INS) | VAF 51/274 reads (19%) | called by mutect2, pindel, varscan2
- NUDCD3 | c.297_298del p.A101Cfs*4 | Frame Shift Del (DEL) | VAF 44/256 reads (17%) | called by pindel, varscan2
- PCDHGC3 | c.1696dup p.Q566Pfs*50 | Frame Shift Ins (INS) | VAF 10/72 reads (14%) | called by mutect2, pindel, varscan2
- PCSK5 | c.859del p.L287Sfs*88 | Frame Shift Del (DEL) | VAF 37/325 reads (11%) | called by mutect2, pindel, varscan2
- POU6F1 | c.1660del p.Q554Rfs*3 | Frame Shift Del (DEL) | VAF 19/94 reads (20%) | called by mutect2, pindel, varscan2
- RAB1A | c.436del p.G147Efs*15 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel, varscan2
- RB1 | c.1604_1605del p.F535Yfs*19 | Frame Shift Del (DEL) | VAF 12/122 reads (10%) | called by mutect2, varscan2
- SP140L | c.1476del p.F492Lfs*17 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | called by mutect2, varscan2
- TAF15 | c.1589del p.G530Afs*116 (on ENST00000605844 / NM_139215.3; = p.G527Afs*116 on NM_003487.4) | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | called by mutect2, pindel, varscan2
- TMEM161A | c.494del p.G165Vfs*39 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | called by mutect2, pindel, varscan2
- ZCCHC10 | c.189dup p.Y64Ifs*4 (on ENST00000509437 / NM_001300818.3; = p.Y42Ifs*4 on NM_017665.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- ACO1 | c.2184C>T p.R728= | Silent (SNP) | VAF 24/195 reads (12%) | catalogued as COSV59376739; called by muse, mutect2, varscan2
- ACSM5 | c.1161C>T p.I387= | Silent (SNP) | VAF 66/742 reads (9%) | catalogued as COSV59369531, COSV59373251; called by muse, mutect2
- AKAP17A | c.399C>T p.D133= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as rs763839188, COSV58308229; called by muse, mutect2
- AKAP6 | c.972G>T p.G324= | Silent (SNP) | VAF 42/215 reads (20%) | catalogued as COSV55204967; called by muse, mutect2, varscan2
- ALOX12B | c.1959C>T p.F653= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs760046576, COSV59870940; called by muse, mutect2, varscan2
- ALPL | c.921G>A p.P307= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1553414111, COSV66375937; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ANKRD17 | c.300C>T p.G100= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV58215425; called by muse, mutect2, varscan2
- AOC3 | c.1020C>T p.G340= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV53824168; called by muse, mutect2, varscan2
- APCDD1 | c.1395G>A p.Q465= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV62372032; called by muse, mutect2
- ATG4C | c.387T>C p.L129= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV58603677; called by muse, mutect2, varscan2
- B3GAT1 | c.955C>T p.L319= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV56994979; called by muse, mutect2, varscan2
- BACH1 | c.810T>C p.C270= | Silent (SNP) | VAF 16/308 reads (5%) | catalogued as rs4817282, COSV54517357; called by muse, mutect2
- BIRC3 | c.303C>T p.S101= | Silent (SNP) | VAF 26/512 reads (5%) | catalogued as rs374571638, COSV54815001; called by muse, mutect2
- BMP2K | c.285A>G p.E95= | Silent (SNP) | VAF 35/291 reads (12%) | catalogued as COSV58591953; called by muse, mutect2, varscan2
- CCDC112 | c.87A>G p.K29= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV65472647; called by muse, mutect2
- CCHCR1 | c.1761G>A p.R587= | Silent (SNP) | VAF 7/115 reads (6%) | catalogued as COSV52545060; called by muse, mutect2
- CDKL5 | c.2520C>T p.R840= | Silent (SNP) | VAF 23/572 reads (4%) | catalogued as rs1037569177, COSV66110202; ClinVar: uncertain significance; called by muse, mutect2
- CHRNB4 | c.672C>T p.Y224= | Silent (SNP) | VAF 59/194 reads (30%) | catalogued as rs201350469, COSV55714651; called by muse, mutect2, varscan2
- COQ6 | c.1338G>A p.T446= | Silent (SNP) | VAF 29/248 reads (12%) | catalogued as rs557785330, COSV53177904; called by muse, mutect2, varscan2
- CPO | c.594C>T p.N198= | Silent (SNP) | VAF 16/308 reads (5%) | catalogued as COSV55938598; called by muse, mutect2
- CSF2RA | c.996C>T p.I332= | Silent (SNP) | VAF 11/116 reads (9%) | catalogued as rs186573135, COSV62623481; ClinVar: likely benign; called by muse, mutect2, varscan2
- CUL5 | c.1836G>A p.E612= | Silent (SNP) | VAF 23/228 reads (10%) | catalogued as COSV67608074; called by muse, mutect2, varscan2
- CYP4F3 | c.210G>A p.S70= | Silent (SNP) | VAF 34/102 reads (33%) | catalogued as rs61734303; called by muse, mutect2, varscan2
- DHX30 | c.2559C>T p.I853= (on ENST00000445061 / NM_138615.3; = p.I814= on NM_014966.3) | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- DLST | c.363C>T p.G121= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as rs1015929036, COSV53165547; called by muse, mutect2
- E2F2 | c.501G>A p.R167= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as rs772518646, COSV62276212; called by muse, mutect2, varscan2
- FBXO24 | c.1452G>A p.Q484= (on ENST00000241071 / NM_033506.3; = p.Q522= on NM_012172.5) | Silent (SNP) | VAF 41/171 reads (24%) | catalogued as COSV53823561; called by muse, mutect2, varscan2
- FBXO38 | c.2694G>A p.K898= (on ENST00000340253 / NM_205836.3; = p.K823= on NM_030793.5) | Silent (SNP) | VAF 29/433 reads (7%) | catalogued as COSV57025802; called by muse, mutect2
- FBXW4 | c.1242T>C p.F414= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV58706650; called by muse, mutect2
- FIGN | c.1758C>T p.D586= | Silent (SNP) | VAF 14/234 reads (6%) | catalogued as COSV60763105; called by muse, mutect2
- FNTB | c.630A>G p.V210= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV55760004; called by muse, mutect2, varscan2
- GCC1 | c.1338G>A p.A446= | Silent (SNP) | VAF 18/123 reads (15%) | catalogued as rs200740651, COSV58461746; called by muse, mutect2, varscan2
- HIBADH | c.912T>C p.S304= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as COSV55311495; called by muse, mutect2
- HP1BP3 | c.793C>T p.L265= | Silent (SNP) | VAF 38/147 reads (26%) | catalogued as COSV56561278; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.330G>A p.T110= | Silent (SNP) | VAF 110/457 reads (24%) | catalogued as rs377583910; called by muse, mutect2, varscan2
- IGSF22 | c.1128G>A p.T376= | Silent (SNP) | VAF 21/258 reads (8%) | catalogued as rs777353843, COSV60030744; called by muse, mutect2
- IQGAP3 | c.3927T>C p.H1309= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV63249342; called by muse, mutect2, varscan2
- KCNA3 | c.724C>T p.L242= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV63900905; called by muse, mutect2
- KIAA1549L | c.4710A>G p.A1570= (on ENST00000321505; = p.A1867= on NM_012194.3) | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV58581690; called by muse, mutect2
- LIMS2 | c.940C>T p.L314= (on ENST00000355119 / NM_001161403.3; = p.L338= on NM_017980.4) | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV61441429; called by muse, mutect2, varscan2
- MECOM | c.2425C>T p.L809= (on ENST00000468789 / NM_001105078.4; = p.L997= on NM_004991.4) | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV52959536, COSV99245159; called by muse, mutect2, varscan2
- MR1 | c.561A>G p.L187= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as COSV51579744; called by muse, mutect2, varscan2
- MRTFB | c.630G>A p.A210= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as rs767667006, COSV100370771, COSV57956206; called by muse, mutect2, varscan2
- MUC16 | c.5262T>C p.S1754= | Silent (SNP) | VAF 16/194 reads (8%) | catalogued as COSV67444622; called by muse, mutect2
- NEUROD6 | c.948C>T p.Y316= | Silent (SNP) | VAF 54/143 reads (38%) | catalogued as rs773060233, COSV51769977; called by muse, mutect2, varscan2
- NMUR1 | c.585C>T p.P195= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV59403446; called by muse, mutect2, varscan2
- OCRL | c.2514C>T p.Y838= | Silent (SNP) | VAF 121/310 reads (39%) | catalogued as rs1325913665, COSV63980077; called by muse, mutect2, varscan2
- ODF1 | c.534G>A p.P178= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as rs773452541, COSV53431550; called by muse, mutect2, varscan2
- OR52E8 | c.516G>T p.L172= | Silent (SNP) | VAF 101/386 reads (26%) | catalogued as COSV66204711, COSV66212270; called by muse, mutect2, varscan2
- PARD3B | c.1368C>T p.T456= | Silent (SNP) | VAF 69/239 reads (29%) | catalogued as COSV62502891; called by muse, mutect2, varscan2
- PCED1A | c.939C>A p.P313= | Silent (SNP) | VAF 4/74 reads (5%) | catalogued as COSV62313275; called by muse, mutect2
- PDLIM3 | c.531C>T p.H177= (on ENST00000284770 / NM_001257963.1; = p.H344= on NM_014476.6) | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as rs200734614; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLEKHG3 | c.2805T>C p.Y935= (on ENST00000394691; = p.Y991= on NM_001308147.2) | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV55977627; called by muse, mutect2
- PPP2R1A | c.894G>A p.V298= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV59042387, COSV59042773; called by muse, mutect2, varscan2
- PPP6R1 | c.714G>A p.L238= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV69799236; called by muse, mutect2
- PRDM4 | c.2073G>A p.Q691= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as COSV57304443; called by muse, mutect2, varscan2
- PUS10 | c.708A>G p.P236= | Silent (SNP) | VAF 11/183 reads (6%) | catalogued as COSV57450542; called by muse, mutect2
- PXK | c.687C>T p.N229= | Silent (SNP) | VAF 30/133 reads (23%) | catalogued as rs780602891, COSV57086616; called by muse, mutect2, varscan2
- RCC2 | c.987C>T p.N329= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV64905261; called by muse, mutect2, varscan2
- SACS | c.8142G>A p.S2714= | Silent (SNP) | VAF 15/128 reads (12%) | catalogued as rs530250252, COSV66534118; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAYSD1 | c.492C>T p.G164= | Silent (SNP) | VAF 72/251 reads (29%) | catalogued as COSV57722792; called by muse, mutect2, varscan2
- SEC24B | c.1146G>A p.E382= | Silent (SNP) | VAF 36/259 reads (14%) | catalogued as rs1332876663, COSV54495382; called by muse, mutect2, varscan2
- SIPA1L1 | c.3165A>G p.S1055= | Silent (SNP) | VAF 28/439 reads (6%) | catalogued as rs201169378, COSV62168368; called by muse, mutect2
- SLC2A1 | c.603C>T p.C201= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as rs1553156091, COSV65286711; ClinVar: likely benign; called by muse, mutect2
- SMURF1 | c.2007C>T p.F669= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs746940837, COSV100705381, COSV62815739; called by mutect2, varscan2
- SPG21 | c.414T>C p.S138= | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as COSV52602076; called by muse, mutect2, varscan2
- SRRT | c.1356C>G p.L452= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV53814943; called by muse, mutect2, varscan2
- THBS1 | c.1590C>T p.D530= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV52949987; called by muse, mutect2, varscan2
- THBS2 | c.267G>A p.Q89= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV64677045; called by muse, mutect2, varscan2
- TICAM1 | c.1203C>T p.H401= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs748521173, COSV50229413; called by muse, mutect2, varscan2
- TREM1 | c.132G>A p.T44= | Silent (SNP) | VAF 45/183 reads (25%) | catalogued as rs771318799, COSV55147722; called by muse, mutect2, varscan2
- TTN | c.6933A>G p.K2311= (on ENST00000591111; = p.K2265= on NM_003319.4) | Silent (SNP) | VAF 118/299 reads (39%) | catalogued as COSV59886839; called by muse, mutect2, varscan2
- TUBB2A | c.429G>A p.T143= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as rs1157028451, COSV61318756; called by muse, mutect2, varscan2
- UNC13B | c.2451G>A p.V817= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV65931279; called by muse, mutect2
- UNC5C | c.2664A>G p.P888= | Silent (SNP) | VAF 44/162 reads (27%) | catalogued as COSV71658085; called by muse, mutect2, varscan2
- USH2A | c.10932G>A p.T3644= | Silent (SNP) | VAF 31/218 reads (14%) | catalogued as rs139989739; called by muse, mutect2, varscan2
- UTP14C | c.855T>C p.I285= | Silent (SNP) | VAF 26/388 reads (7%) | catalogued as COSV73000563; called by muse, mutect2
- ZDHHC3 | c.123C>T p.D41= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs764511897, COSV56100544; called by muse, mutect2, varscan2
- ZNF16 | c.1401A>G p.G467= | Silent (SNP) | VAF 20/155 reads (13%) | catalogued as COSV52762647; called by muse, mutect2, varscan2
- ZNF536 | c.1086T>C p.G362= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV62818469; called by muse, mutect2, varscan2
- ZNF611 | c.1869G>A p.K623= | Silent (SNP) | VAF 174/695 reads (25%) | catalogued as COSV60539548; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850970 C>T | 3'Flank (SNP) | VAF 20/79 reads (25%) | catalogued as rs753313142; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851141 G>A | 3'Flank (SNP) | VAF 15/264 reads (6%) | called by muse, mutect2
- AMER1 | c.*3749G>A | 3'UTR (SNP) | VAF 25/127 reads (20%) | catalogued as rs747727608, COSV100365730, COSV57654831; called by muse, mutect2, varscan2
- AMFR | c.*411C>T | 3'UTR (SNP) | VAF 10/27 reads (37%) | catalogued as rs372252237; called by muse, mutect2, varscan2
- LIM2 | c.175+11del | Intron (DEL) | VAF 6/42 reads (14%) | catalogued as rs776721409; called by mutect2, pindel
- PRDM15 | c.-334G>T | 5'UTR (SNP) | VAF 3/45 reads (7%) | catalogued as COSV54148865; called by muse, mutect2
- RNU7-174P | chr8:80559711 C>G | 5'Flank (SNP) | VAF 24/127 reads (19%) | called by muse, mutect2, varscan2
- SLC5A1 | chr22:32039551 C>T | 5'Flank (SNP) | VAF 36/160 reads (23%) | called by muse, mutect2, varscan2
- SPACA6 | chr19:51693267 G>T | 5'Flank (SNP) | VAF 2/8 reads (25%) | called by muse, mutect2
- ZNF99 | c.*568C>A | 3'UTR (SNP) | VAF 166/447 reads (37%) | catalogued as COSV68054729; called by muse, mutect2, varscan2
